Gene-level copy-number profile of tumor specimen TCGA-24-1434-01A from TCGA case TCGA-24-1434, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 59.7 years (21,810 days).
Specimen TCGA-24-1434-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.9b0d1252-3106-4bec-b8ff-35098deca4d5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1434-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f420af7b-16b4-4bb9-bdff-c85fbbde9750

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,349; copy number 2: 26,790; copy number 3: 22,512; copy number 4: 3,291; copy number 5: 1,660; copy number 6: 190; copy number 8: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1434-01A-01D-0472-01): tumor purity 0.63, ploidy 2.61, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,873 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:105,655,461–117,139,389, 175 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:117,544,205–198,222,513, 1,478 genes, copy number 5 (broad region; genes not listed).
- chr4:56,288,485–57,495,844, 36 genes, copy number 6: RNU6-197P, AC022267.1, MRPL22P1, AASDH, RPL7AP31, AC068620.1, PPAT, AC068620.2, AC068620.3, PAICS, SRP72, ARL9, THEGL, GLDCP1, HOPX, AC108215.1, RPL17P20, AC022483.1, RN7SL492P, RN7SL357P, SPINK2, Metazoa_SRP, Y_RNA, REST, AC069307.1, NOA1, POLR2B, RNU6-998P, IGFBP7, UBE2CP3, IGFBP7-AS1, AC111197.1, AC105390.1, RPS26P24, LINC02380, AC013724.1.
- chr10:28,652,630–28,682,932, 4 genes, copy number 5: RNU4ATAC6P, TPRKBP1, RNU6-1067P, BAMBI.
- chr10:28,743,745–28,796,113, 3 genes, copy number 5: AL355376.1, RNU6-270P, LINC00837.
- chr10:77,730,766–80,778,088, 88 genes, copy number 6 (broad region; genes not listed).
- chr19:29,775,504–31,349,436, 23 genes, copy number 8: AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1, TSHZ3, LINC01791.
- chr20:31,341,371–32,858,751, 66 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,928. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
